Somatic mutation profile of tumor specimen BA2546D (aliquot aq-BA2546D) from BEATAML1.0 case 2259, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,095 days).
Specimen BA2546D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc28b71-7c8c-4de2-bce0-1a0f44b6e3d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2648D (Solid Tissue Normal), aliquot aq-BA2648D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49fcac42-b144-4ada-8010-a09711963b9d

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, Splice Site 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>T p.X307_splice | Splice Site (SNP) | VAF 123/279 reads (44%) | hotspot (GDC flag); catalogued as COSV52693974, COSV52706655, COSV52945558, COSV53066011; called by muse, mutect2, varscan2
- MRPL14 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2
- PAK5 | c.1616+1G>C p.X539_splice | Splice Site (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- RIMS1 | c.3734C>A p.T1245K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2
- KIAA0319 | c.1002A>G p.E334= | Silent (SNP) | VAF 64/142 reads (45%) | called by muse, varscan2
- SCAF1 | c.2400G>A p.E800= | Silent (SNP) | VAF 48/121 reads (40%) | called by mutect2, varscan2
- AC068587.7 | chr8:12659568 C>T | 5'Flank (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2
- ATP6V1B2 | c.-6G>A | 5'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as rs776402221; called by muse, varscan2
